Somatic mutation profile of tumor specimen TCGA-BA-4077-01B (aliquot TCGA-BA-4077-01B-01D-1434-08) from TCGA case TCGA-BA-4077, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 45.3 years (16,536 days).
Specimen TCGA-BA-4077-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f41e036-b7df-4352-97a8-2aa76265731d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-4077-10A (Blood Derived Normal), aliquot TCGA-BA-4077-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/545cedc8-ba2d-4ab3-827b-d75b2e231c91

The open-access MAF lists 326 somatic variants for this specimen: 236 protein-altering or splice-affecting, 82 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 200, Silent 82, Nonsense Mutation 20, Frame Shift Del 7, In Frame Del 3, Splice Site 3, Intron 3, Frame Shift Ins 2, RNA 2, 3'UTR 2, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 111/182 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55948973, COSV99712609; called by muse, mutect2, varscan2
- ACSL4 | c.1720C>A p.L574I (on ENST00000340800 / NM_022977.2; = p.L533I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100538665, COSV61613592; called by muse, mutect2, varscan2
- ADAMTS7 | c.4198G>A p.E1400K | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.192); catalogued as COSV101183127; called by muse, mutect2
- ADNP | c.312G>C p.R104S | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV100823774; called by muse, mutect2, varscan2
- AFDN | c.719C>G p.S240* | Nonsense Mutation (SNP) | VAF 60/431 reads (14%) | catalogued as COSV100653120; called by muse, mutect2, varscan2
- AGBL5 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.122); catalogued as rs1264422740, COSV100549169; called by muse, mutect2, varscan2
- AGO1 | c.2369G>T p.R790L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100940861, COSV64594869; called by muse, mutect2, varscan2
- AHNAK | c.14966C>G p.A4989G | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV99947990; called by muse, mutect2
- AJAP1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.093); catalogued as rs753991951, COSV65452187; called by muse, varscan2
- ANGPTL2 | c.830A>T p.D277V | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401862; called by muse, mutect2, varscan2
- ANKS6 | c.1418A>G p.Q473R | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.968); catalogued as COSV100782314; called by muse, mutect2, varscan2
- ARFIP1 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100617188; called by muse, mutect2
- ARHGAP4 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 50/460 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV100603798, COSV100604090, COSV100604207; called by muse, mutect2, varscan2
- ARHGAP6 | c.1698G>C p.Q566H | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100273083; called by muse, varscan2
- ARHGEF16 | c.1475C>G p.S492C | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV101000464, COSV101000591; called by muse, mutect2, varscan2
- ARID1A | c.5698G>C p.D1900H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.687); catalogued as COSV100252108, COSV61378661; called by muse, mutect2
- ATF7IP | c.3350G>A p.G1117E | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV99661789; called by muse, mutect2, varscan2
- ATG2B | c.4126G>A p.D1376N | Missense Mutation (SNP) | VAF 39/453 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV99952097; called by muse, mutect2
- BBX | c.1365G>C p.K455N | Missense Mutation (SNP) | VAF 162/241 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100361753; called by muse, varscan2
- BCHE | c.958C>G p.P320A | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs749805953, COSV100012689; called by muse, mutect2, varscan2
- BMP15 | c.1123A>T p.S375C | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99399399; called by muse, mutect2, varscan2
- BMP3 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99261777; called by muse, mutect2
- BMP3 | c.48C>G p.C16W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV51084928; called by muse, mutect2
- BOC | c.39G>T p.R13S | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99848880; called by muse, mutect2, varscan2
- C18orf21 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV99321629; called by muse, mutect2, varscan2
- C9orf131 | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100398141; called by muse, mutect2, varscan2
- CABIN1 | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99573458; called by muse, mutect2, varscan2
- CACNB3 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776284677, COSV99974945; called by muse, mutect2, varscan2
- CAMK2B | c.746T>C p.I249T | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99323147; called by muse, mutect2, varscan2
- CAPZA1 | c.658-1G>T p.X220_splice | Splice Site (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99583253; called by muse, mutect2, varscan2
- CCDC191 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 44/660 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1487448885, COSV99878362; called by muse, mutect2
- CCDC30 | c.715G>T p.V239L (on ENST00000340612; = p.V196L on NM_001080850.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.054); catalogued as COSV100501409; called by muse, mutect2, varscan2
- CCDC43 | c.441G>C p.E147D | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100189012; called by muse, mutect2, varscan2
- CCDC63 | c.1639A>G p.S547G | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV99960791; called by muse, mutect2, varscan2
- CCDC73 | c.821A>C p.Q274P | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100067739; called by muse, mutect2, varscan2
- CCNG2 | c.345_347del p.E115del | In Frame Del (DEL) | VAF 68/246 reads (28%) | catalogued as rs749760461; called by pindel, varscan2
- CCP110 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101195294; called by muse, mutect2, varscan2
- CD163L1 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as COSV100550207; called by muse, mutect2, varscan2
- CENPO | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 289/911 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53166029, COSV99568458; called by muse, mutect2, varscan2
- CFAP221 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV54659789, COSV99732053; called by muse, mutect2, varscan2
- CHD3 | c.5296G>T p.D1766Y (on ENST00000330494 / NM_001005273.3; = p.D1732Y on NM_005852.4) | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100177210; called by muse, mutect2, varscan2
- CHST5 | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV100292018, COSV60338899; called by muse, varscan2
- CHST5 | c.761G>C p.W254S | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as COSV100292019, COSV60337948; called by muse, mutect2, varscan2
- CIDEA | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as COSV100255137, COSV57598151; called by muse, varscan2
- CLEC3B | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV56109791, COSV99944581; called by muse, mutect2, varscan2
- CLUH | c.1865A>T p.K622M (on ENST00000435359; = p.K660M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101425778; called by muse, varscan2
- COL16A1 | c.958G>T p.V320F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV99594735; called by muse, mutect2, varscan2
- CPA6 | c.623G>A p.W208* | Nonsense Mutation (SNP) | VAF 55/131 reads (42%) | catalogued as COSV99913818; called by muse, mutect2, varscan2
- CRAMP1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.298); catalogued as COSV51960759; called by muse, mutect2, varscan2
- CRY1 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99150883; called by muse, mutect2, varscan2
- CTAGE1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV101194567; called by muse, mutect2, varscan2
- CUL1 | c.1497G>C p.E499D | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100296723; called by muse, mutect2, varscan2
- DCAF5 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV100432305; called by muse, mutect2
- DCP2 | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as rs760057225, COSV101203918; called by muse, mutect2, varscan2
- DEAF1 | c.647A>T p.K216M | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100102117; called by muse, mutect2, varscan2
- DIAPH1 | c.1425G>C p.E475D | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as COSV99526737; called by muse, mutect2, varscan2
- DLGAP5 | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs1416669966, COSV99903949; called by muse, mutect2, varscan2
- DPY19L2 | c.1770C>G p.I590M | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100193598; called by muse, mutect2, varscan2
- DRC1 | c.2174C>G p.S725C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99718010; called by muse, mutect2, varscan2
- DST | c.8218G>A p.E2740K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV99757381; called by muse, mutect2
- DUSP6 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.51); catalogued as COSV99684078; called by mutect2, varscan2
- EDEM2 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100993793; called by muse, mutect2, varscan2
- EED | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 72/147 reads (49%) | catalogued as COSV54559347; called by muse, mutect2, varscan2
- EIF1 | c.298-1G>A p.X100_splice | Splice Site (SNP) | VAF 40/175 reads (23%) | catalogued as COSV100179530; called by muse, mutect2, varscan2
- ELMOD3 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 12/156 reads (8%) | catalogued as COSV100226357; called by muse, mutect2
- EPHA2 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs2291806, COSV100626173, COSV64452977; called by muse, mutect2, varscan2
- ERBB2 | c.2224G>C p.D742H | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54077439; called by muse, mutect2
- ERCC8 | c.1177G>C p.E393Q (on ENST00000265038; = p.E374Q on NM_000082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.503); catalogued as COSV99410468; called by muse, mutect2, varscan2
- ESPL1 | c.6309G>C p.K2103N | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99229434; called by muse, mutect2, varscan2
- ETFA | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99144238; called by muse, mutect2, varscan2
- ETV4 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs776306922, COSV100081499, COSV60043769; called by muse, mutect2, varscan2
- FBN1 | c.2000G>C p.R667T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV100355494; called by muse, mutect2, varscan2
- FBXL13 | c.447G>C p.E149D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100501746, COSV57543740; called by muse, mutect2, varscan2
- FGF17 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV100846156; called by muse, mutect2, varscan2
- FLG | c.8557C>A p.H2853N | Missense Mutation (SNP) | VAF 268/1658 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs757231985, COSV64238031, COSV64242563; called by muse, mutect2
- FLOT2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV67528813; called by muse, mutect2, varscan2
- FOXJ2 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 21/316 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as COSV99368657; called by muse, mutect2
- FRY | c.6807G>C p.K2269N | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100969405; called by muse, mutect2, varscan2
- GALNT2 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100795795; called by muse, mutect2, varscan2
- GEMIN8 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV100257060; called by muse, mutect2, varscan2
- GLS2 | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs781271836, COSV100358386; called by muse, mutect2, varscan2
- GOLGB1 | c.9106G>C p.D3036H | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV100511083; called by muse, mutect2
- GPKOW | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV99332678; called by muse, mutect2
- GPR179 | c.2926G>T p.A976S (on ENST00000621958; = p.A975S on NM_001004334.4) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.767); catalogued as rs754216240; called by muse, mutect2, varscan2
- GPRASP1 | c.3151C>T p.Q1051* | Nonsense Mutation (SNP) | VAF 161/430 reads (37%) | catalogued as COSV100851021; called by muse, mutect2, varscan2
- GRM5 | c.1957C>G p.L653V | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as COSV100552477, COSV100553042; called by muse, mutect2, varscan2
- HAP1 | c.1815G>A p.M605I (on ENST00000310778 / NM_001367460.1; = p.M553I on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 204/567 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV100169772; called by muse, varscan2
- HAP1 | c.1723G>C p.E575Q (on ENST00000310778 / NM_001367460.1; = p.E523Q on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 206/670 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV100169784; called by muse, varscan2
- HCN4 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs1465495839, COSV99983874; called by muse, mutect2, varscan2
- HCRTR2 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100904405; called by muse, mutect2, varscan2
- HERC1 | c.7620A>T p.E2540D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV101496633; called by muse, mutect2, varscan2
- HIBADH | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs371063501, COSV55317193; called by muse, mutect2, varscan2
- ICAM1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 47/145 reads (32%) | catalogued as COSV99320913; called by muse, mutect2, varscan2
- IFT140 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1420709766, COSV54153948; ClinVar: uncertain significance; called by muse, mutect2
- IGDCC4 | c.435C>G p.F145L | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV100732952; called by muse, mutect2, varscan2
- INTS10 | c.2068C>G p.L690V | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as COSV101208702; called by muse, mutect2, varscan2
- KCNF1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as rs1337505283, COSV99705759, COSV99705791; called by muse, mutect2, varscan2
- KIF15 | c.1526G>C p.R509T | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100392921; called by muse, mutect2, varscan2
- KIFBP | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 66/193 reads (34%) | catalogued as COSV100741398; called by muse, mutect2, varscan2
- KMT2D | c.3391C>G p.P1131A | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV56479692, COSV99983038; called by muse, mutect2, varscan2
- KMT2E | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99996480; called by muse, mutect2, varscan2
- LDLR | c.2124G>A p.M708I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs758248798, COSV99369565; called by muse, mutect2, varscan2
- LHX6 | c.529G>C p.E177Q (on ENST00000373755 / NM_001242334.2; = p.E206Q on NM_014368.5) | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV100493475, COSV100493576; called by muse, mutect2, varscan2
- LILRB5 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV100300518; called by muse, mutect2
- LINGO1 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.073); catalogued as COSV100796416; called by muse, mutect2, varscan2
- LMLN | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 36/369 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100218649; called by muse, mutect2
- LRP6 | c.2535C>G p.I845M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99743584; called by muse, mutect2, varscan2
- LRSAM1 | c.1465G>C p.E489Q | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100031598; called by muse, mutect2, varscan2
- LSAMP | c.675G>C p.K225N | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV100371151; called by muse, mutect2, varscan2
- LSS | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs150614553; called by muse, mutect2, varscan2
- MAGEB1 | c.771C>A p.Y257* | Nonsense Mutation (SNP) | VAF 36/125 reads (29%) | catalogued as rs766373792, COSV66775251, COSV66775580; called by muse, mutect2, varscan2
- MARCHF10 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 100/492 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100248276; called by muse, mutect2, varscan2
- MARCHF7 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV99373837; called by muse, mutect2, varscan2
- MED13 | c.2935C>G p.Q979E | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV101181145; called by muse, mutect2, varscan2
- MFSD2A | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 153/458 reads (33%) | catalogued as COSV100861701; called by muse, mutect2, varscan2
- MIA3 | c.1264G>C p.D422H | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV100719472; called by muse, mutect2, varscan2
- MXRA5 | c.8132G>T p.C2711F | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99477529; called by muse, mutect2, varscan2
- MYLPF | c.64T>C p.F22L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100363095; called by muse, mutect2, varscan2
- MYO1F | c.1853G>C p.R618T | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100596772; called by muse, mutect2, varscan2
- MYOM3 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as COSV100293069; called by muse, mutect2, varscan2
- NAB2 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55666453; called by muse, mutect2, varscan2
- NABP2 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1215225444, COSV99907548; called by muse, mutect2, varscan2
- NALCN | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1288858780, COSV51944292; called by muse, mutect2
- NAPRT | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs962870447, COSV99063644; called by muse, mutect2, varscan2
- NDC1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99323694; called by muse, mutect2, varscan2
- NEK1 | c.3610G>C p.E1204Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.248); catalogued as COSV101455706; called by muse, mutect2
- NEUROD6 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99774093; called by muse, mutect2, varscan2
- NLGN1 | c.374G>C p.R125T | Missense Mutation (SNP) | VAF 30/652 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.02); catalogued as rs1367569483, COSV100849463, COSV64333907; called by muse, mutect2
- NLRC5 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV99347563; called by muse, mutect2, varscan2
- NOC2L | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 77/510 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as COSV100498060; called by muse, mutect2, varscan2
- NPY5R | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 91/443 reads (21%) | catalogued as COSV100642818; called by muse, mutect2, varscan2
- NRXN1 | c.1022C>A p.S341Y | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as COSV100455549; called by muse, mutect2, varscan2
- NUP210L | c.4760G>A p.R1587K | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99668315; called by muse, mutect2
- NXPH2 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99740816; called by muse, mutect2, varscan2
- OR4K15 | c.568C>G p.L190V (on ENST00000305051; = p.L166V on NM_001005486.1) | Missense Mutation (SNP) | VAF 79/320 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100521064; called by muse, mutect2, varscan2
- OR51T1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs867447772, COSV59023663, COSV59026348; called by muse, varscan2
- OR6B3 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs772087271, COSV100097360; called by muse, mutect2, varscan2
- P2RX1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.371); catalogued as COSV99844792; called by muse, mutect2
- P4HTM | c.702C>G p.I234M | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100637565; called by muse, mutect2, varscan2
- PCM1 | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.735); catalogued as COSV100279203; called by muse, mutect2, varscan2
- PDE3A | c.3015C>G p.I1005M | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100762271; called by muse, mutect2, varscan2
- PFKFB1 | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | PolyPhen probably damaging (0.981); catalogued as COSV100895746; called by muse, mutect2
- PHKG2 | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100079630; called by muse, mutect2, varscan2
- PHRF1 | c.2441C>T p.S814L (on ENST00000264555 / NM_001286581.2; = p.S813L on NM_020901.4) | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV99202606; called by muse, mutect2
- PLG | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as CM068074, COSV51982818, COSV99804791; called by muse, mutect2, varscan2
- PLG | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99804792; called by muse, mutect2, varscan2
- PLK2 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.007); catalogued as rs746929950, COSV57108406, COSV57109367; called by mutect2, varscan2
- POLR3A | c.2722G>C p.D908H | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100965690; called by muse, mutect2
- PPP1R16B | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760522412, COSV100239594; called by muse, mutect2, varscan2
- PRPF6 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99412174; called by muse, mutect2
- PRR14 | c.1385T>A p.M462K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99788446; called by muse, mutect2, varscan2
- PRR14 | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs761394824, COSV99788447; called by muse, mutect2, varscan2
- PTCH2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs768496761, COSV100942147; called by muse, mutect2, varscan2
- PTPN13 | c.6046G>A p.E2016K (on ENST00000411767 / NM_080683.3; = p.E1997K on NM_006264.3) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100364939; called by muse, mutect2
- PTPN23 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99650703; called by muse, mutect2, varscan2
- PTPRS | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99511121; called by muse, mutect2, varscan2
- PTPRS | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99511126; called by muse, mutect2, varscan2
- RABGAP1 | c.1395G>C p.K465N | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.116); catalogued as rs933826836, COSV101020108, COSV101020166; called by muse, mutect2, varscan2
- RBMXL1 | c.1028G>C p.R343T | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV99556457; called by muse, mutect2, varscan2
- RFFL | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 19/156 reads (12%) | catalogued as COSV99265388; called by muse, mutect2, varscan2
- RGS12 | c.4195C>T p.R1399W (on ENST00000336727; = p.R751W on NM_198227.2) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs777921323, COSV58750078; called by muse, mutect2, varscan2
- RGS14 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.934); catalogued as COSV101281724; called by muse, mutect2, varscan2
- RPP30 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99520922; called by muse, mutect2, varscan2
- RTF1 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 44/457 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV101047916; called by muse, mutect2, varscan2
- RXRB | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100807741; called by muse, mutect2
- SDAD1 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100668643; called by muse, varscan2
- SDHA | c.571T>C p.C191R | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV99371786; called by muse, mutect2, varscan2
- SEC24C | c.2739G>T p.K913N | Missense Mutation (SNP) | VAF 50/331 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100226937; called by muse, mutect2, varscan2
- SERBP1 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as COSV100769127; called by muse, mutect2
- SFN | c.79A>G p.K27E | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); catalogued as COSV100212841; called by muse, mutect2, varscan2
- SFN | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 53/175 reads (30%) | catalogued as COSV100212842; called by muse, mutect2, varscan2
- SLC10A7 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99389838, COSV99390722; called by muse, mutect2, varscan2
- SLC3A2 | c.1825C>G p.L609V | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV100101437; called by muse, mutect2, varscan2
- SLC9C2 | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV100876807; called by muse, mutect2
- SMARCAL1 | c.102G>C p.Q34H | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.592); catalogued as rs752194629, COSV100619922; called by muse, mutect2, varscan2
- SMOC2 | c.1111G>A p.E371K (on ENST00000356284 / NM_001166412.2; = p.E382K on NM_022138.3) | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62443754; called by muse, mutect2, varscan2
- SORBS2 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99511398; called by muse, mutect2, varscan2
- SOX14 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1267502029, COSV100048249; called by muse, mutect2, varscan2
- SPAG7 | c.243-1G>T p.X81_splice | Splice Site (SNP) | VAF 38/103 reads (37%) | catalogued as COSV52779052; called by muse, mutect2, varscan2
- SPATA5 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99915740; called by muse, mutect2
- SPICE1 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as COSV99871484; called by muse, mutect2, varscan2
- SPZ1 | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs775842332, COSV57064100; called by muse, mutect2, varscan2
- SPZ1 | c.1230C>G p.F410L | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV99698210; called by muse, mutect2, varscan2
- SRSF5 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV101275292; called by muse, mutect2, varscan2
- STAG3 | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 155/464 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99444759; called by muse, mutect2, varscan2
- STAM | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101092318; called by muse, mutect2
- STON2 | c.2128G>A p.E710K (on ENST00000649389 / NM_001366849.2; = p.E653K on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as COSV50844070; called by muse, mutect2, varscan2
- SUSD2 | c.620C>G p.S207* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100844336; called by muse, mutect2, varscan2
- SVEP1 | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.395); catalogued as COSV100238275; called by muse, mutect2, varscan2
- SWAP70 | c.254T>C p.F85S | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100013848; called by muse, mutect2, varscan2
- TCP1 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as rs777942713, COSV100364870, COSV100364940; called by muse, mutect2, varscan2
- TLN1 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 55/614 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100147859, COSV59204459; called by muse, mutect2
- TMEM132D | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs1210889863, COSV101242916; called by muse, mutect2, varscan2
- TOP1 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV63692791, COSV63696820; called by muse, mutect2
- TOX4 | c.1649C>G p.S550C | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.712); catalogued as COSV99398372; called by muse, mutect2, varscan2
- TP53BP1 | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99780767; called by muse, mutect2, varscan2
- TRPM5 | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs367610086; called by muse, mutect2, varscan2
- TTC17 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as COSV99235479; called by muse, mutect2, varscan2
- TTN | c.94109C>T p.S31370F (on ENST00000591111; = p.S23946F on NM_003319.4) | Missense Mutation (SNP) | VAF 38/293 reads (13%) | PolyPhen benign (0.01); catalogued as COSV100617870; called by muse, mutect2, varscan2
- TUBAL3 | c.1275C>G p.F425L | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV100990546; called by muse, mutect2, varscan2
- TUBAL3 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs371530868; called by muse, varscan2
- TUBGCP6 | c.4979C>T p.S1660F | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99955794; called by muse, mutect2, varscan2
- UBXN11 | c.491C>T p.S164L (on ENST00000374221 / NM_183008.2; = p.S131L on NM_145345.2) | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.866); catalogued as COSV100122686; called by muse, mutect2, varscan2
- UGCG | c.1181T>A p.V394E | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV100958962; called by muse, mutect2, varscan2
- UNC5D | c.2573G>T p.R858I | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54774656, COSV99776019; called by muse, mutect2, varscan2
- UNC79 | c.5887G>C p.D1963H (on ENST00000393151 / NM_001346218.2; = p.D1786H on NM_020818.5) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99828330; called by muse, mutect2, varscan2
- UPP2 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as COSV99134990; called by muse, mutect2
- USE1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768507747, COSV99812519; called by muse, mutect2, varscan2
- USP3 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV99165729; called by muse, mutect2
- VIRMA | c.4576G>A p.D1526N | Missense Mutation (SNP) | VAF 40/484 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV99888644; called by muse, mutect2
- WAPL | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 42/418 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV100076907; called by muse, mutect2, varscan2
- WDR77 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 34/167 reads (20%) | catalogued as COSV99330855; called by muse, mutect2, varscan2
- WNK3 | c.1715G>C p.G572A | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100671582, COSV63616107; called by muse, mutect2, varscan2
- WTAP | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100603351; called by muse, mutect2, varscan2
- ZNF142 | c.2030G>A p.R677Q (on ENST00000411696 / NM_001379660.1; = p.R477Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs759292993, COSV101376949; called by muse, varscan2
- ZNF273 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.015); catalogued as COSV100139364; called by muse, mutect2, varscan2
- ZNF273 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV100139367; called by muse, mutect2, varscan2
- ZNF331 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs1399113338, COSV53476072; called by muse, mutect2, varscan2
- ZNF486 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV100631300; called by muse, mutect2, varscan2
- ZNF628 | c.1782C>A p.F594L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV99220105; called by muse, mutect2
- ZZEF1 | c.1019T>G p.V340G | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV101067880; called by muse, mutect2, varscan2
- ARHGAP15 | c.1024_1030del p.D342Sfs*12 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | called by pindel, varscan2
- CSAG3 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 72/395 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSMD3 | c.2164del p.L722Cfs*24 (on ENST00000297405 / NM_001363185.1; = p.L618Cfs*24 on NM_052900.3) | Frame Shift Del (DEL) | VAF 94/223 reads (42%) | called by mutect2, pindel, varscan2
- DENND1B | c.1907_1908insA p.S636Rfs*13 | Frame Shift Ins (INS) | VAF 24/98 reads (24%) | called by mutect2, pindel*, varscan2
- FNDC7 | c.1968_1977delinsA p.N656_T659delinsK | In Frame Del (DEL) | VAF 45/188 reads (24%) | called by pindel, varscan2*
- HSPD1 | c.1209del p.L404* | Frame Shift Del (DEL) | VAF 48/189 reads (25%) | called by mutect2, pindel, varscan2
- KDM5B | c.439del p.C147Afs*45 | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | called by mutect2, pindel, varscan2
- LRPPRC | c.2045del p.L682Qfs*6 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | called by mutect2, pindel*, varscan2
- NRIP3 | c.260_266del p.K87Tfs*11 | Frame Shift Del (DEL) | VAF 70/254 reads (28%) | called by mutect2, pindel, varscan2
- POLR2A | c.5446C>G p.P1816A | Missense Mutation (SNP) | VAF 156/462 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PRUNE2 | c.6253_6254insGTA p.E2085delinsGK | In Frame Ins (INS) | VAF 91/329 reads (28%) | called by mutect2, varscan2*
- PRUNE2 | c.6248_6251dup p.E2085Wfs*2 | Frame Shift Ins (INS) | VAF 60/294 reads (20%) | called by mutect2*, pindel, varscan2
- SYN1 | c.1231del p.V411Sfs*256 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- TFCP2 | c.485_487del p.D162_P163delinsA | In Frame Del (DEL) | VAF 81/299 reads (27%) | called by mutect2, pindel, varscan2
- ALOX15 | c.276C>T p.V92= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV99541467; called by muse, mutect2, varscan2
- APPL1 | c.1296A>G p.G432= | Silent (SNP) | VAF 81/126 reads (64%) | catalogued as rs761918738, COSV99897789; called by muse, mutect2, varscan2
- ARHGAP33 | c.2754C>T p.L918= | Silent (SNP) | VAF 43/158 reads (27%) | catalogued as rs772107035, COSV50270418; called by muse, mutect2, varscan2
- ASZ1 | c.387G>A p.L129= | Silent (SNP) | VAF 22/155 reads (14%) | catalogued as rs775278203, COSV99498087; called by muse, mutect2, varscan2
- BDKRB1 | c.552G>C p.L184= | Silent (SNP) | VAF 36/243 reads (15%) | catalogued as COSV99387911; called by muse, mutect2, varscan2
- BICDL1 | c.1680C>T p.I560= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs201184033, COSV57494332; called by mutect2, varscan2
- BMP15 | c.1122G>T p.G374= | Silent (SNP) | VAF 61/286 reads (21%) | catalogued as COSV53140634, COSV99399396; called by muse, mutect2, varscan2
- CAPS | c.250C>A p.R84= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as COSV50385751, COSV99222348; called by muse, mutect2, varscan2
- CBL | c.252C>T p.I84= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV99876492; called by muse, mutect2
- CCDC63 | c.1200C>T p.Y400= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs141258896; called by muse, mutect2, varscan2
- CCNB3 | c.3693C>T p.I1231= | Silent (SNP) | VAF 23/228 reads (10%) | catalogued as COSV99329252; called by muse, mutect2, varscan2
- CFTR | c.1782G>A p.L594= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV50097184; called by muse, mutect2, varscan2
- CILP2 | c.3007C>A p.R1003= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs751122502, COSV52279043, COSV99364822; called by muse, mutect2, varscan2
- COL6A3 | c.7062G>A p.Q2354= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV99799095; called by muse, mutect2, varscan2
- CPS1 | c.3603C>A p.V1201= | Silent (SNP) | VAF 121/196 reads (62%) | catalogued as COSV51830027, COSV99243262; called by muse, mutect2, varscan2
- CRYBG2 | c.4764G>C p.V1588= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV100366756; called by muse, mutect2
- DNAH5 | c.4573C>T p.L1525= | Silent (SNP) | VAF 14/214 reads (7%) | catalogued as COSV99450859; called by muse, mutect2
- DST | c.11940G>A p.L3980= (on ENST00000361203 / NM_001374722.1; = p.L1568= on NM_015548.5) | Silent (SNP) | VAF 42/462 reads (9%) | catalogued as COSV99757377; called by muse, mutect2
- EEF1A1 | c.33C>T p.V11= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs770526323, COSV100303346; called by muse, mutect2, varscan2
- EFNA4 | c.150C>G p.L50= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV99665070; called by muse, mutect2, varscan2
- FAM120C | c.2673G>A p.Q891= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as COSV100070186; called by muse, mutect2, varscan2
- FCGBP | c.12240C>G p.V4080= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- FFAR2 | c.792C>G p.L264= | Silent (SNP) | VAF 56/262 reads (21%) | catalogued as COSV55832678; called by muse, mutect2, varscan2
- GABRR2 | c.984C>G p.L328= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as COSV101298984; called by muse, mutect2, varscan2
- GALNTL5 | c.636G>C p.L212= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs140077291, COSV101217847; called by muse, mutect2, varscan2
- GNA15 | c.192C>T p.I64= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99505255; called by muse, mutect2, varscan2
- GPBP1 | c.435G>A p.E145= | Silent (SNP) | VAF 11/181 reads (6%) | catalogued as COSV99302864; called by muse, mutect2
- GRPR | c.267C>T p.L89= | Silent (SNP) | VAF 32/424 reads (8%) | catalogued as COSV100977673; called by muse, mutect2
- HTR1A | c.1119C>T p.S373= | Silent (SNP) | VAF 104/306 reads (34%) | catalogued as COSV100109139; called by muse, mutect2, varscan2
- IGHV3-11 | c.15G>C p.L5= | Silent (SNP) | VAF 16/412 reads (4%) | called by muse, mutect2
- INTS2 | c.1824G>A p.S608= | Silent (SNP) | VAF 72/186 reads (39%) | catalogued as rs578079823, COSV52152182; called by muse, mutect2, varscan2
- JAK2 | c.306C>T p.F102= | Silent (SNP) | VAF 30/303 reads (10%) | catalogued as COSV101074934; called by muse, mutect2
- KANSL2 | c.42G>T p.G14= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV63479353; called by muse, mutect2, varscan2
- KCNJ15 | c.748C>T p.L250= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV60811001; called by muse, mutect2, varscan2
- LRRC10 | c.270G>T p.L90= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV100825500; called by muse, mutect2, varscan2
- MAP3K5 | c.3534C>T p.F1178= | Silent (SNP) | VAF 53/173 reads (31%) | catalogued as COSV100752933; called by muse, mutect2, varscan2
- MRGPRX2 | c.207C>A p.L69= | Silent (SNP) | VAF 16/170 reads (9%) | catalogued as COSV100316769; called by muse, mutect2
- MSLNL | c.1008C>A p.L336= | Silent (SNP) | VAF 13/160 reads (8%) | catalogued as COSV99558404; called by muse, mutect2
- NDRG3 | c.543G>C p.L181= (on ENST00000349004 / NM_032013.4; = p.L169= on NM_022477.4) | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV100675396; called by muse, mutect2, varscan2
- NLE1 | c.82C>T p.L28= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100681016; called by muse, mutect2, varscan2
- NPTN | c.1089G>A p.R363= | Silent (SNP) | VAF 45/365 reads (12%) | catalogued as COSV99766549; called by muse, mutect2, varscan2
- NRK | c.831C>G p.V277= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99688172; called by muse, mutect2, varscan2
- NUDT19 | c.555C>G p.L185= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs763821867, COSV101229233; called by muse, varscan2
- NUP37 | c.435C>T p.D145= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as rs767035951, COSV51839991; called by muse, mutect2, varscan2
- OR2T2 | c.747G>C p.V249= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100737697; called by muse, mutect2, varscan2
- OR4N2 | c.132C>T p.L44= | Silent (SNP) | VAF 122/396 reads (31%) | catalogued as rs267603909, COSV100269535; called by muse, mutect2, varscan2
- OR51L1 | c.282C>T p.I94= | Silent (SNP) | VAF 108/310 reads (35%) | catalogued as COSV58625929; called by muse, mutect2
- OR6B3 | c.21C>G p.T7= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as COSV100097359; called by muse, mutect2, varscan2
- PCDHA9 | c.2100G>A p.L700= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as rs1554144555, COSV100969430, COSV100969708; called by muse, mutect2
- PCDHB4 | c.768A>G p.L256= | Silent (SNP) | VAF 62/237 reads (26%) | catalogued as COSV99522277; called by muse, mutect2, varscan2
- PCDHGC5 | c.156G>C p.L52= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as COSV52766304, COSV99340628; called by muse, mutect2, varscan2
- PCNX1 | c.3117C>T p.L1039= | Silent (SNP) | VAF 54/407 reads (13%) | catalogued as rs531165168, COSV99455994; called by muse, mutect2, varscan2
- PLD1 | c.879G>C p.T293= | Silent (SNP) | VAF 235/392 reads (60%) | catalogued as COSV100577542, COSV100578315; called by muse, mutect2, varscan2
- PLXNA3 | c.840C>T p.I280= | Silent (SNP) | VAF 41/286 reads (14%) | catalogued as rs149751983, COSV63753205; called by mutect2, varscan2
- POLR1E | c.1317G>A p.L439= (on ENST00000377792 / NM_001282766.1; = p.L377= on NM_022490.4) | Silent (SNP) | VAF 42/256 reads (16%) | catalogued as COSV100905413; called by muse, mutect2, varscan2
- PPFIA1 | c.291C>T p.L97= | Silent (SNP) | VAF 20/393 reads (5%) | catalogued as COSV54139474, COSV99557594; called by muse, mutect2
- PRRC2A | c.1968G>A p.L656= | Silent (SNP) | VAF 165/444 reads (37%) | catalogued as COSV101051224; called by muse, mutect2, varscan2
- PTCHD3 | c.1149G>A p.V383= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV101438921; called by muse, mutect2, varscan2
- RECQL5 | c.726G>A p.L242= | Silent (SNP) | VAF 236/665 reads (35%) | catalogued as rs747334511, COSV99502875; called by muse, mutect2, varscan2
- SEZ6L2 | c.2235C>T p.L745= (on ENST00000308713 / NM_001114099.3; = p.L675= on NM_012410.4) | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV100435552; called by muse, mutect2, varscan2
- SHC4 | c.813C>A p.L271= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV100194727; called by muse, mutect2, varscan2
- SLC32A1 | c.1284G>A p.L428= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV54148832; called by muse, mutect2, varscan2
- SLC6A13 | c.381C>G p.V127= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100569984; called by muse, mutect2, varscan2
- SLC9A7 | c.1941G>T p.L647= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV100092280; called by muse, mutect2, varscan2
- SMG7 | c.1491C>T p.P497= | Silent (SNP) | VAF 113/324 reads (35%) | catalogued as COSV100750383; called by muse, mutect2, varscan2
- SNRNP35 | c.210C>G p.V70= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV100644573; called by muse, mutect2, varscan2
- SNTA1 | c.345C>T p.S115= | Silent (SNP) | VAF 16/260 reads (6%) | catalogued as COSV99458769; called by muse, mutect2
- SPATA31D1 | c.1521C>G p.L507= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as rs1005220728, COSV100782833; called by muse, mutect2, varscan2
- TBC1D10A | c.825C>T p.F275= | Silent (SNP) | VAF 22/185 reads (12%) | catalogued as COSV53163348, COSV53166104; called by muse, mutect2, varscan2
- TCTN1 | c.963G>C p.V321= (on ENST00000551590 / NM_001173975.3; = p.V307= on NM_024549.6) | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as COSV100886099; called by muse, mutect2, varscan2
- TECTA | c.2298G>A p.L766= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV99880222; called by muse, mutect2, varscan2
- TFRC | c.1728G>C p.L576= | Silent (SNP) | VAF 43/374 reads (11%) | catalogued as COSV100786519; called by muse, mutect2, varscan2
- TLR4 | c.1710T>C p.S570= (on ENST00000355622 / NM_138554.5; = p.S530= on NM_003266.4) | Silent (SNP) | VAF 73/134 reads (54%) | catalogued as COSV100842787; called by muse, mutect2, varscan2
- TRIM14 | c.354C>G p.L118= | Silent (SNP) | VAF 55/317 reads (17%) | catalogued as COSV100419615, COSV58353344; called by muse, mutect2, varscan2
- TRIM75P | c.853C>T p.L285= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs1322661878; called by muse, mutect2, varscan2
- USP42 | c.2484G>C p.A828= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV100084605, COSV60362423; called by muse, mutect2, varscan2
- ZBTB20 | c.1578C>T p.F526= (on ENST00000474710 / NM_001164342.2; = p.F453= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 40/257 reads (16%) | catalogued as rs1156700089, COSV61862040; called by muse, mutect2, varscan2
- ZFP36L1 | c.699C>T p.S233= | Silent (SNP) | VAF 30/354 reads (8%) | catalogued as rs750342662, COSV100322738; called by muse, mutect2
- ZIK1 | c.378T>G p.V126= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as COSV100277527; called by muse, mutect2, varscan2
- ZNF142 | c.1947G>A p.L649= (on ENST00000411696 / NM_001379660.1; = p.L449= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV101376950; called by muse, varscan2
- ZNF559 | c.345A>G p.R115= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs925179627, COSV100416580; called by muse, mutect2, varscan2
- ZNF835 | c.813C>T p.I271= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV101606362; called by muse, mutect2, varscan2
- ATG16L1 | c.954+1132G>A | Intron (SNP) | VAF 57/113 reads (50%) | catalogued as COSV100731270, COSV100731330; called by muse, mutect2, varscan2
- CCNQP1 | n.636G>C | RNA (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- DBN1 | c.86+1294G>T | Intron (SNP) | VAF 11/73 reads (15%) | catalogued as COSV99446134; called by muse, mutect2, varscan2
- DCHS2 | n.2343C>G | RNA (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100252174; called by muse, mutect2, varscan2
- PHYHD1 | c.*25C>T | 3'UTR (SNP) | VAF 30/146 reads (21%) | catalogued as rs375648347; called by muse, mutect2, varscan2
- SPTB | c.6345+58C>G | Intron (SNP) | VAF 42/292 reads (14%) | catalogued as COSV100731148; called by muse, mutect2
- TEX2 | chr17:64146461 G>C | 3'Flank (SNP) | VAF 50/279 reads (18%) | called by muse, mutect2, varscan2
- UVSSA | c.*9605G>A | 3'UTR (SNP) | VAF 145/326 reads (44%) | catalogued as rs146370789; called by muse, mutect2, varscan2
